Somatic mutation profile of tumor specimen C3N-03225-01 (aliquot CPT0191570006) from CPTAC case C3N-03225, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 56.9 years (20,775 days).
Specimen C3N-03225-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ac8c0ec-efc0-4f16-9c76-75c140b6d4a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03225-71 (Blood Derived Normal), aliquot CPT0193270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f06e1bce-4f43-4e33-a071-f055ee29fbbc

The open-access MAF lists 74 somatic variants for this specimen: 52 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 11, Nonsense Mutation 6, Intron 6, RNA 3, 3'UTR 2, Splice Site 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 58/299 reads (19%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- ARHGAP21 | c.2492C>G p.S831C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs752692388; called by mutect2, varscan2
- BRCA1 | c.3431A>G p.Q1144R | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs773638815; called by muse, mutect2, varscan2
- CABIN1 | c.3532G>A p.G1178S | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs146818859; called by muse, mutect2, varscan2
- CSNK2A3 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 32/469 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757842632, COSV57150094, COSV99923526; called by muse, mutect2
- DNMT3B | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 70/628 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.135); catalogued as rs1217503696, COSV52423002; called by muse, mutect2, varscan2
- FBLN1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549459139; called by muse, mutect2, varscan2
- FBN2 | c.6800G>A p.R2267H | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs868504219, COSV52531968; called by muse, mutect2, varscan2
- ITGA5 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 35/315 reads (11%) | catalogued as COSV53220715; called by muse, mutect2, varscan2
- KLK13 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV50067058; called by muse, mutect2
- KNSTRN | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV51105900; called by muse, mutect2
- LATS2 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.382); catalogued as rs761798256; called by muse, mutect2, varscan2
- MACROD2 | c.1058A>T p.D353V (on ENST00000642719; = p.D325V on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs1476181580; called by muse, mutect2
- MGAM | c.4588G>A p.A1530T | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs772302459, COSV72074752; called by muse, mutect2, varscan2
- NOS1 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1042913420, COSV57606613; called by muse, mutect2
- OR51M1 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 90/370 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs778999949; called by muse, mutect2, varscan2
- PDZRN3 | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769665096; called by muse, mutect2, varscan2
- PTGER4 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as rs746407417, COSV56720918, COSV56722276; called by muse, mutect2
- RASSF9 | c.231C>G p.Y77* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as rs1473804465; called by muse, mutect2, varscan2
- RNF10 | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs766105279; called by muse, mutect2
- RSPH10B | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748138700; called by mutect2, varscan2
- SGIP1 | c.1264G>T p.V422L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.785); catalogued as COSV99390877; called by muse, mutect2
- SLC10A2 | c.878A>G p.Y293C | Missense Mutation (SNP) | VAF 101/319 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414214287; called by muse, mutect2, varscan2
- SLC12A2 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52477419; called by muse, mutect2
- TNXB | c.4574G>A p.R1525H (on ENST00000647633; = p.R1278H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.061); catalogued as rs368042869; called by muse, mutect2, varscan2
- ZNF334 | c.2006C>A p.S669* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs377245233; called by muse, mutect2, varscan2
- ZNF598 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1471418297, COSV70910991; called by muse, mutect2
- ADGRB2 | c.4102G>T p.G1368* | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- ADGRD2 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANKRD30A | c.1033G>C p.A345P (on ENST00000611781; = p.A289P on NM_052997.2) | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2
- ASTN1 | c.2681C>A p.P894Q | Missense Mutation (SNP) | VAF 23/286 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- BRD9 | c.268-25_268-1del p.X90_splice | Splice Site (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel
- CCK | c.320G>C p.S107T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX56 | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2
- DYNC1H1 | c.11702A>T p.Y3901F | Missense Mutation (SNP) | VAF 62/499 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM53C | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 106/456 reads (23%) | called by muse, mutect2, varscan2
- FRYL | c.2364A>G p.I788M | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); called by muse, mutect2
- IFNAR1 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- IGSF10 | c.2734G>C p.G912R | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- IK | c.1670A>T p.Y557F | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- INSC | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 38/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IPO5 | c.3010G>T p.E1004* | Nonsense Mutation (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- KIDINS220 | c.4219A>G p.S1407G | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.276); called by muse, mutect2
- OXR1 | c.2507G>C p.W836S (on ENST00000442977 / NM_001198532.1; = p.W808S on NM_018002.3) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB9 | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2
- RHD | c.190T>G p.F64V | Missense Mutation (SNP) | VAF 129/1262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3E | c.996del p.S333Vfs*54 | Frame Shift Del (DEL) | VAF 22/191 reads (12%) | called by mutect2, pindel, varscan2
- TAF2 | c.1103G>T p.W368L | Missense Mutation (SNP) | VAF 48/602 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAV40 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- UNC5A | c.1871_1873del p.X624_splice | Splice Site (DEL) | VAF 30/85 reads (35%) | called by pindel, varscan2
- ZDBF2 | c.1833C>G p.H611Q | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF605 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DACH2 | c.327G>T p.V109= | Silent (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- DCHS1 | c.9051A>G p.G3017= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs1427550075; called by muse, mutect2
- DSC3 | c.1977T>A p.A659= | Silent (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- IK | c.1671C>T p.Y557= | Silent (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- MCHR1 | c.567G>A p.T189= | Silent (SNP) | VAF 19/416 reads (5%) | catalogued as rs979674247; called by muse, mutect2
- PCDHGB4 | c.1653C>T p.D551= | Silent (SNP) | VAF 60/617 reads (10%) | catalogued as COSV53924614; called by muse, mutect2
- PLXNA3 | c.2691G>A p.E897= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV63753594; called by muse, mutect2, varscan2
- RAB40C | c.426C>T p.R142= | Silent (SNP) | VAF 24/496 reads (5%) | catalogued as rs777101065; called by muse, mutect2
- RBPMS2 | c.262C>T p.L88= | Silent (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- SLITRK2 | c.393A>T p.L131= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV59428731; called by muse, mutect2, varscan2
- TRBC2 | c.321C>T p.D107= | Silent (SNP) | VAF 13/186 reads (7%) | catalogued as rs782203883; called by muse, mutect2
- C12orf43 | c.*1736A>G | 3'UTR (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2, varscan2
- CD96 | c.*40T>C | 3'UTR (SNP) | VAF 8/229 reads (3%) | called by muse, mutect2
- KIAA0895L | c.848-116G>A | Intron (SNP) | VAF 27/131 reads (21%) | catalogued as rs1265160211; called by muse, mutect2, varscan2
- KRT17P1 | n.1251T>A | RNA (SNP) | VAF 29/278 reads (10%) | called by muse, mutect2, varscan2
- MIR146A | n.29G>T | RNA (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
- MIR424 | n.38C>A | RNA (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- NEB | c.11602-3067C>T | Intron (SNP) | VAF 27/432 reads (6%) | catalogued as rs1287669175; called by muse, mutect2
- PTPRC | c.3330+30T>C | Intron (SNP) | VAF 27/240 reads (11%) | called by muse, mutect2, varscan2
- RBMS2 | c.66+17600_66+17603del | Intron (DEL) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- SLC9A3 | c.1647+11C>T | Intron (SNP) | VAF 31/260 reads (12%) | catalogued as rs760662073; called by muse, mutect2, varscan2
- ZNF419 | c.298+192C>T | Intron (SNP) | VAF 23/164 reads (14%) | catalogued as COSV55659316; called by muse, mutect2, varscan2
